Gene-level copy-number profile of tumor specimen TCGA-AJ-A3I9-01A from TCGA case TCGA-AJ-A3I9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 52.4 years (19,139 days).
Specimen TCGA-AJ-A3I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.6dfbe539-ee68-49dd-a0df-6c74cecdda29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3I9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c4bfb76-3e66-4aaf-937a-86bae7b8a451

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,158; copy number 2: 49,904; copy number 3: 1,652; copy number 4: 95; copy number 5: 7; copy number 8: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3I9-01A-11D-A227-01): tumor purity 0.94, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:94,791,643–94,793,106, 1 gene, copy number 8: AP003692.1.
- chr8:101,492,439–101,669,726, 3 genes, copy number 5: GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,689,093, 1 gene, copy number 5: AP000426.1.
- chr8:119,873,717–120,050,918, 1 gene, copy number 5 (within-gene range 3–5): DEPTOR.
- chr8:120,052,180–120,373,573, 2 genes, copy number 5 (within-gene range 3–5): AC091563.1, COL14A1.
- chr8:127,735,434–127,742,951, 1 gene, copy number 8: MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 8: MIR1204.

Autosomal genes at a single copy (total copy number 1): 8,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
